Somatic mutation profile of tumor specimen MP2PRT-PASMGK-TMP1-A (aliquot MP2PRT-PASMGK-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASMGK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,604 days).
Specimen MP2PRT-PASMGK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9c91386-d5f5-4a6e-9994-d0fb8194c925.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASMGK-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASMGK-NB1-B-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a07db09-f785-4839-90cc-fd20107b1bb9

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN8 | c.899A>G p.D300G | Missense Mutation (SNP) | VAF 139/298 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.127); catalogued as rs781755828; called by muse, mutect2, varscan2
- DES | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 133/371 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770258461, COSV100900481; called by muse, mutect2, varscan2
- EPHA8 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 43/409 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); catalogued as rs776890427; called by muse, mutect2, varscan2
- NUTM2A | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1435419981; called by mutect2, varscan2
- PLEC | c.9862C>T p.R3288C (on ENST00000322810 / NM_201380.4; = p.R3178C on NM_000445.5) | Missense Mutation (SNP) | VAF 73/519 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs781903647; called by muse, mutect2, varscan2
- SLC36A1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 64/289 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs777711037; called by muse, mutect2, varscan2
- TM9SF4 | c.1770C>A p.F590L | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as COSV54106267; called by muse, mutect2, varscan2
- EIF2S2 | c.317A>T p.D106V | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2
- FADS2 | c.1111_1113del p.F371del | In Frame Del (DEL) | VAF 38/315 reads (12%) | called by pindel, varscan2
- PRKCB | c.905G>C p.R302P | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- SCN10A | c.5248A>G p.K1750E | Missense Mutation (SNP) | VAF 31/407 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- NIN | c.1168C>T p.L390= | Silent (SNP) | VAF 172/388 reads (44%) | called by muse, mutect2, varscan2
- ZNF517 | c.792C>T p.G264= | Silent (SNP) | VAF 19/621 reads (3%) | called by muse, mutect2
